Gene-level copy-number profile of tumor specimen TCGA-04-1652-01A from TCGA case TCGA-04-1652, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.9 years (28,101 days).
Specimen TCGA-04-1652-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.18004841-99c3-4b9d-910e-63a47d4287d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1652-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9056b26b-32fc-4b44-a183-3430b3bb3570

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 2,064; copy number 2: 13,353; copy number 3: 24,112; copy number 4: 14,126; copy number 5: 3,868; copy number 6: 1,647; copy number 7: 203; copy number 8: 265; copy number 11: 69; copy number 16: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1652-01A-01D-0577-01): tumor purity 0.86, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,006,936, 44 genes (within-gene range 0–1): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 599 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:165,206,929–171,938,715, 103 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr4:56,977,722–57,855,271, 14 genes, copy number 8 (within-gene range 4–8): POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1.
- chr8:46,028,804–61,944,180, 240 genes, copy number 7–16 (broad region; genes not listed).
- chr12:23,529,504–24,562,544, 1 gene, copy number 7 (within-gene range 6–7): SOX5.
- chr12:24,212,421–25,409,445, 25 genes, copy number 7: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1.
- chr12:25,423,600–25,441,052, 3 genes, copy number 7: AC092451.2, FAM133GP, TUBB4BP1.
- chr14:27,258,717–27,845,286, 1 gene, copy number 7 (within-gene range 4–7): AL390334.1.
- chr19:18,204,730–21,427,577, 162 genes, copy number 7–8 (broad region; genes not listed).
- chr19:28,294,093–30,713,538, 50 genes, copy number 11 (within-gene range 5–11): AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1.

Autosomal genes at a single copy (total copy number 1): 1,434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
